Surgical pathology report (de-identified scan), TCGA case TCGA-12-1092, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Duke, specimen TCGA-12-1092-01B (Primary Tumor).

[page 1 of 2]
Patient: [REDACTED]

12-1892

AP Surgical Pathology: Additional Info [REDACTED] Acc# [REDACTED]

Surg Path

CLINICAL HISTORY:

[REDACTED] developed some problems with his left side. He is a patient who was found to have a malignant glioma. He has noted drooling from the left side of his face. He has noted walking into things on the left side.

[REDACTED] MRI [REDACTED]: The patient is status post right parietal craniotomy. There has been interval debulking of a large right parietal heterogeneously enhancing tumor. When compared to prior examination. The amount of enhancing lesion has decreased, though there is still a heterogeneous focus of enhancement in the right parietal lobe involving the ependymal surface of the posterior horn of the right lateral ventricle which measures at least 2.3 x 1.8 x 1.7 cm. There is extensive surrounding hyperintense T2 and FLAIR signal, compatible with vasogenic edema. There is a nodular focus of enhancement within the right lateral ventricle.

GROSS EXAMINATION:

A. "Brain tissue (AF1)", received fresh for frozen section is a 1.5 x 1 x 1 cm aggregate of pink-tan soft tissue. Representative section has been previously frozen as AF1, the frozen section remnant of which is submitted in block A1. Additional representative section is submitted in block A2, with the remainder retained in formalin.

B. "Brain tissue", received in formalin is a 1.5 x 1 x 0.4 cm aggregate of pink-tan soft tissue. Representative section is submitted in block B1, with the remainder retained in formalin.

INTRA OPERATIVE CONSULTATION:

A. "Brain tissue": AF1- glioblastoma [REDACTED]

MICROSCOPIC EXAMINATION:

Microscopic examination shows a malignant glial neoplasm that is densely cellular and pleomorphic with poorly differentiated tumor cells, mitotic activity, microvascular proliferation, and extensive necrosis.

DIAGNOSIS:

A. "BRAIN TISSUE" (BIOPSY):

GLIOBLASTOMA (WHO GRADE IV).

B. "BRAIN TISSUE" (BIOPSY):

GLIOBLASTOMA (WHO GRADE IV).

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED]
Electronically signed: [REDACTED]

ADDENDUM 1:

Please see Image Cytometry Report [REDACTED] for results of supplementary tests.

FISH INTERPRETATION SUMMARY:

[page 2 of 2]
12-10-07

CHROMOSOME 7 CENTROMERE - POLYSOMY (71% OF TUMOR CELLS EXHIBIT POLYSOMY)

EGFR - POLYSOMY (68% OF TUMOR CELLS EXHIBIT POLYSOMY)

CHROMOSOME 10 CENTROMERE - POLYSOMY (83% OF TUMOR CELLS EXHIBIT POLYSOMY)

PTEN - POLYSOMY (73% OF TUMOR CELLS EXHIBIT POLYSOMY)

2 OF 4 ABNORMAL MARKERS.

COMMENT: A MULTIVARIATE SURVIVAL ANALYSIS OF [REDACTED] PATIENTS WITH GLIOBLASTOMAS REVEALS THAT THE HAZARD OF SHORT SURVIVAL AMONG PATIENTS WITH 0-2 ABNORMAL MARKERS (OUT OF 4) WAS SIGNIFICANTLY LOWER THAN THAT FOUND WITH PATIENTS WITH 4 ABNORMAL MARKERS EVEN AFTER ADJUSTMENT FOR AGE EFFECT.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED]

Electronically signed: [REDACTED]

ADDENDUM 2:

IMMUNOHISTOCHEMICAL LABELING INDEX OF TUMOR CELLS:

TISSUE TYPE: BRAIN TISSUE CONTAINING GLIOBLASTOMA (WHO GRADE IV; [REDACTED] BLOCK A2).

MGMT - POSITIVE (50% OF TUMOR CELLS)

EGFR wt - POSITIVE (3+ IN 70% OF TUMOR CELLS)

EGFR vIII - NEGATIVE

PTEN - POSITIVE (3+ IN 75% OF TUMOR CELLS)

pS6 - POSITIVE (3+ IN 30% OF TUMOR CELLS)

pAKT - NEGATIVE (2+ IN 5% OF TUMOR CELLS)

Please see Image Cytometry Report [REDACTED] for results of supplementary tests.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED]

Electronically signed: [REDACTED]

Performed by: [REDACTED]

Source: NCI Genomic Data Commons file d335f903-9c4f-4cd3-bff8-898c60bb92a5 (TCGA-12-1092.B594D67E-8E3F-48A6-A14F-9F187B5DC507.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).